Surgical pathology report (de-identified scan), TCGA case TCGA-DD-A3A0, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-A3A0-01A (Primary Tumor).

Patient Key:

Surgical date:

TISSUE DESCRIPTION:

Left gastric lymph node (3.2 x 1.2 x 0.8 cm), diaphragm biopsy (1.1 x 1 x 0.7 cm) and segment III and IV liver (675 grams; 22 x 13 x 7 cm). A1, B1, C1, C2, C3, C4, C5

DIAGNOSIS:

Liver, segment III and IV, resection: Grade 2 (of 4) hepatocellular carcinoma forms a 8 x 6 x 2 cm partially necrotic mass. The margins of resection are free of tumor by at least 1 cm. There is no vascular invasion. The uninvolved liver parenchyma is noncirrhotic.

Lymph node, left gastric, excision: Reactive lymphoid hyperplasia.

Diaphragm, biopsy: Calcified fibrous nodule.

1CD-0-3

carcinoma, hepatocellular, Nos 8170/3

Site: liver C22.0

fw
9/22/11

H:PAI Discrepancy		☒

Source: NCI Genomic Data Commons file c28077a0-1c6e-40fb-9795-b936ec8bbbea (TCGA-DD-A3A0.C9E146D4-77FF-4877-8DA6-2E5D912F33C6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).